Somatic mutation profile of tumor specimen C3N-03433-02 (aliquot CPT0246540006) from CPTAC case C3N-03433, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 76.7 years (28,032 days).
Specimen C3N-03433-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c09e783b-2f32-4858-ad4b-85141854bd56.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03433-31 (Blood Derived Normal), aliquot CPT0246580002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5c70af87-fe96-4e4c-a491-f1389175c668

The open-access MAF lists 584 somatic variants for this specimen: 395 protein-altering or splice-affecting, 104 silent, 85 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 317, Silent 104, Intron 47, Nonsense Mutation 25, Frame Shift Del 23, 3'UTR 11, Splice Region 9, RNA 9, In Frame Del 9, Splice Site 7, 5'Flank 7, 3'Flank 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.8364G>A p.W2788* | Nonsense Mutation (SNP) | VAF 123/273 reads (45%) | catalogued as rs397507981, CM128955; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 85/205 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057521796; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.1513G>C p.E505Q | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as COSV65312246; called by muse, mutect2, varscan2
- ACSBG1 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 36/416 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.023); catalogued as rs1282580279, COSV99357266; called by muse, mutect2
- ADCY7 | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs781143896; called by muse, mutect2, varscan2
- ADGRG6 | c.3184G>A p.E1062K | Missense Mutation (SNP) | VAF 92/666 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV51588413; called by muse, mutect2, varscan2
- AGAP4 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 52/345 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.431); catalogued as rs1240345024; called by muse, mutect2, varscan2
- AGFG2 | c.443dup p.D149Rfs*33 | Frame Shift Ins (INS) | VAF 70/438 reads (16%) | catalogued as rs776472051; called by mutect2, pindel, varscan2
- ASB17 | c.192C>G p.D64E | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.089); catalogued as COSV52409592; called by muse, mutect2, varscan2
- C10orf71 | c.450C>A p.F150L | Missense Mutation (SNP) | VAF 158/336 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60511944; called by muse, mutect2, varscan2
- CCDC141 | c.172G>T p.D58Y | Missense Mutation (SNP) | VAF 13/321 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101330524; called by muse, mutect2
- CCDC66 | c.1946T>G p.L649R (on ENST00000394672 / NM_001353147.1; = p.L615R on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/194 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs750774831, COSV58303984; called by muse, mutect2, varscan2
- CCND1 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 33/561 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.201); catalogued as COSV57120446; called by muse, mutect2
- CFAP45 | c.20G>A p.G7D | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as COSV63650213; called by muse, mutect2, varscan2
- CHD7 | c.7723G>A p.E2575K | Missense Mutation (SNP) | VAF 35/308 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0.096); catalogued as COSV71109188; called by muse, mutect2, varscan2
- CLASP2 | c.1751G>T p.R584I | Missense Mutation (SNP) | VAF 34/152 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as rs749160482; called by muse, mutect2, varscan2
- COL22A1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 137/510 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV100279861; called by muse, mutect2, varscan2
- CTNNBL1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 46/174 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100799909; called by muse, mutect2, varscan2
- DCHS1 | c.8986C>A p.P2996T | Missense Mutation (SNP) | VAF 86/402 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.829); catalogued as COSV54998269; called by muse, mutect2, varscan2
- DCLK1 | c.1051G>A p.G351S | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.017); catalogued as rs1251929920; called by muse, mutect2, varscan2
- DDB2 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 90/468 reads (19%) | catalogued as rs1314761808; called by muse, mutect2, varscan2
- DES | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 313/781 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.095); catalogued as rs397516697, COSV64660570, COSV64661110; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH3 | c.11792C>G p.S3931C | Missense Mutation (SNP) | VAF 81/564 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1460103100; called by muse, mutect2, varscan2
- DNAH6 | c.7315G>T p.E2439* | Nonsense Mutation (SNP) | VAF 50/326 reads (15%) | catalogued as COSV99407471; called by muse, mutect2, varscan2
- DNMT3B | c.-8A>C | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as rs993839654; called by muse, mutect2
- ECM1 | c.886G>C p.E296Q | Missense Mutation (SNP) | VAF 186/692 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.133); catalogued as COSV60871868; called by muse, mutect2, varscan2
- ELAVL2 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 54/394 reads (14%) | catalogued as COSV56356526; called by muse, mutect2, varscan2
- ELF5 | c.377G>T p.R126L (on ENST00000312319 / NM_198381.2; = p.R116L on NM_001422.4) | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as rs371514980, COSV56628705; called by muse, mutect2, varscan2
- ENTPD1 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 15/490 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.038); catalogued as rs1268980941; called by muse, mutect2
- EPS8L3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.023); catalogued as rs755469602; called by muse, mutect2
- ERN1 | c.2436G>A p.M812I | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as rs771417342; called by muse, mutect2, varscan2
- FAT3 | c.11615G>C p.G3872A | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.505); catalogued as COSV53163952; called by muse, mutect2, varscan2
- FBXO6 | c.665A>T p.D222V | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs997086283; called by muse, mutect2
- FCGBP | c.6974G>A p.R2325H | Missense Mutation (SNP) | VAF 119/1757 reads (7%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.74); catalogued as rs1456127049; called by muse, mutect2
- FHAD1 | c.3639G>C p.A1213= | Splice Region (SNP) | VAF 20/70 reads (29%) | catalogued as rs999565529; called by muse, mutect2
- FMNL3 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 107/540 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs760549436; called by muse, mutect2, varscan2
- FTCD | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 137/622 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52425627; called by muse, mutect2, varscan2
- GABRE | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 133/295 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760319267; called by muse, mutect2, varscan2
- GALNT3 | c.1759C>T p.Q587* | Nonsense Mutation (SNP) | VAF 72/359 reads (20%) | catalogued as rs1462404203; called by muse, mutect2, varscan2
- GSDME | c.939C>G p.I313M | Missense Mutation (SNP) | VAF 259/489 reads (53%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.564); catalogued as rs556679282; called by muse, mutect2, varscan2
- H3C4 | c.232G>A p.D78N | Missense Mutation (SNP) | VAF 140/927 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs142669882; called by muse, mutect2, varscan2
- HEXA | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 36/756 reads (5%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV51506017; called by muse, mutect2
- IDUA | c.313C>T p.R105W | Missense Mutation (SNP) | VAF 100/486 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs779553529, COSV56103555; called by muse, mutect2, varscan2
- IQCF1 | c.605C>T p.S202L | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as rs1248122761; called by muse, mutect2
- IRS2 | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 60/616 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.201); catalogued as rs780007007; called by muse, mutect2
- KLF14 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 124/652 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs782804960; called by mutect2, varscan2
- KRTAP10-7 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 164/448 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.496); catalogued as rs782766311; called by muse, mutect2, varscan2
- LETM2 | c.767C>A p.S256* (on ENST00000379957 / NM_001286819.2; = p.S161* on NM_144652.3) | Nonsense Mutation (SNP) | VAF 22/116 reads (19%) | catalogued as COSV52687816; called by muse, mutect2, varscan2
- LILRB5 | c.181G>C p.D61H | Missense Mutation (SNP) | VAF 115/783 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.088); catalogued as rs1360439046, COSV100300790; called by muse, mutect2, varscan2
- LPAR6 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as rs750415786, COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LRRC59 | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 46/251 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746271050; called by muse, mutect2, varscan2
- LTBP3 | c.3358G>A p.D1120N | Missense Mutation (SNP) | VAF 56/332 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.048); catalogued as rs1045991961; called by muse, mutect2, varscan2
- MDGA2 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 95/749 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.3); catalogued as COSV67806403; called by muse, mutect2, varscan2
- MINPP1 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 48/217 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV64354365, COSV64355804; called by muse, mutect2, varscan2
- MPHOSPH10 | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 64/553 reads (12%) | SIFT tolerated (0.64); PolyPhen benign (0.053); catalogued as COSV54913807; called by muse, mutect2, varscan2
- MPRIP | c.2417G>A p.R806Q | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.92); catalogued as rs767133274; called by muse, mutect2, varscan2
- MUC1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 100/718 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.336); catalogued as COSV100104914; called by muse, varscan2
- MUC12 | c.5518G>C p.D1840H (on ENST00000379442; = p.D1697H on NM_001164462.1) | Missense Mutation (SNP) | VAF 271/1194 reads (23%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.866); catalogued as COSV65198584; called by muse, mutect2, varscan2
- NCOR2 | c.4989C>A p.H1663Q | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1333254097; called by muse, mutect2, varscan2
- NLRP4 | c.730G>A p.D244N | Missense Mutation (SNP) | VAF 65/527 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.645); catalogued as rs775533945, COSV100017297, COSV56712882; called by muse, mutect2, varscan2
- NOS1 | c.1890G>A p.W630* | Nonsense Mutation (SNP) | VAF 117/286 reads (41%) | catalogued as COSV57620278; called by muse, mutect2, varscan2
- NPHP1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 128/719 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100338371, COSV100338555; called by muse, mutect2, varscan2
- NR1I2 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 216/520 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs773969078; called by muse, mutect2, varscan2
- NUDT19 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 94/546 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371717452; called by muse, varscan2
- NUP155 | c.1285G>A p.D429N (on ENST00000231498 / NM_153485.3; = p.D370N on NM_004298.4) | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV51527914, COSV51529369; called by muse, mutect2, varscan2
- OTOF | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1297164465; called by muse, mutect2, varscan2
- OTX1 | c.96G>A p.P32= | Splice Region (SNP) | VAF 22/87 reads (25%) | catalogued as rs771256830, COSV56995668; called by muse, mutect2
- PAQR8 | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 66/332 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV62442408; called by muse, mutect2, varscan2
- PARD3B | c.3088C>T p.R1030W (on ENST00000406610 / NM_001302769.2; = p.R961W on NM_057177.7) | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1472369911; called by muse, mutect2, varscan2
- PBX1 | c.1235C>A p.S412* | Nonsense Mutation (SNP) | VAF 44/500 reads (9%) | catalogued as COSV63343859; called by muse, mutect2
- PCDHA7 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 302/768 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65346413; called by muse, mutect2, varscan2
- PCDHB13 | c.1808C>A p.S603* | Nonsense Mutation (SNP) | VAF 278/985 reads (28%) | catalogued as COSV53396206; called by muse, mutect2, varscan2
- PCDHB9 | c.2048C>A p.A683D | Missense Mutation (SNP) | VAF 374/1404 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.394); catalogued as rs782583106, COSV53379359; called by muse, mutect2, varscan2
- PCDHGA12 | c.727G>T p.A243S | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV52777491; called by muse, mutect2, varscan2
- PGK2 | c.570G>A p.M190I | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs753310289, COSV59162947; called by muse, mutect2, varscan2
- PKD1 | c.7487C>T p.T2496M | Missense Mutation (SNP) | VAF 201/550 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs3952944, COSV51919895; called by muse, mutect2, varscan2
- PPP1R37 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1372989347, COSV55526397; called by muse, varscan2
- PPP6R3 | c.127A>C p.K43Q | Missense Mutation (SNP) | VAF 58/1302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs376684893, COSV99677440; called by muse, mutect2
- PRB4 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.763); catalogued as rs1280878599; called by muse, mutect2, varscan2
- PRKCG | c.811G>A p.V271M | Missense Mutation (SNP) | VAF 36/260 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.095); catalogued as rs375466358; called by muse, mutect2, varscan2
- PYGB | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 99/239 reads (41%) | catalogued as rs768749787; called by muse, mutect2, varscan2
- RINL | c.1210C>T p.P404S (on ENST00000591812 / NM_001195833.2; = p.P290S on NM_198445.4) | Missense Mutation (SNP) | VAF 39/391 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs777872922; called by muse, mutect2, varscan2
- RNF187 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 32/239 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs1030185199, COSV59959857, COSV59960193; called by muse, mutect2, varscan2
- RSPH10B | c.1662T>A p.N554K | Missense Mutation (SNP) | VAF 32/381 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV61755457; called by muse, mutect2
- RTL10 | c.127G>C p.V43L | Missense Mutation (SNP) | VAF 99/622 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.348); catalogued as rs747125641; called by muse, mutect2, varscan2
- SEMA3E | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 50/499 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV57094602, COSV57096944; called by muse, mutect2, varscan2
- SHANK1 | c.6364C>G p.H2122D | Missense Mutation (SNP) | VAF 45/404 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV53258114; called by muse, mutect2, varscan2
- SLC22A25 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 100/312 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.67); catalogued as rs866704269, COSV60594594; called by muse, mutect2, varscan2
- SLC26A1 | c.22C>G p.L8V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1245314431; called by muse, mutect2, varscan2
- SLC29A4 | c.452G>C p.S151T | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV51874194; called by muse, mutect2, varscan2
- SLC4A1 | c.80C>G p.P27R | Missense Mutation (SNP) | VAF 56/295 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.109); catalogued as COSV52259183; called by muse, mutect2, varscan2
- SLC4A11 | c.1458C>G p.F486L | Missense Mutation (SNP) | VAF 116/789 reads (15%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as COSV66261522; called by muse, mutect2, varscan2
- SMARCC2 | c.3334G>A p.A1112T | Missense Mutation (SNP) | VAF 56/474 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.034); catalogued as rs751730460; called by muse, varscan2
- SPATA16 | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 68/370 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs777422983, COSV63531110; called by muse, mutect2, varscan2
- STXBP5L | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 42/249 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV56529838; called by muse, mutect2, varscan2
- SUMF1 | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 125/319 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as rs374724319; called by muse, mutect2, varscan2
- TBC1D25 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 96/211 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV100952147; called by muse, mutect2, varscan2
- TEKT1 | c.421G>C p.E141Q | Missense Mutation (SNP) | VAF 43/436 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs781363875; called by muse, mutect2, varscan2
- TEKT1 | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1180389263; called by muse, mutect2, varscan2
- THBS2 | c.355G>A p.G119S | Missense Mutation (SNP) | VAF 90/683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827770; called by muse, mutect2, varscan2
- TIPARP | c.1073G>C p.R358T | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs750560844; called by muse, mutect2, varscan2
- TJP2 | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 81/568 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1224386813; called by muse, mutect2, varscan2
- TMEM88B | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 131/368 reads (36%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.531); catalogued as rs893918229; called by muse, mutect2, varscan2
- TNFAIP3 | c.1367G>A p.G456E | Missense Mutation (SNP) | VAF 71/415 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV52800696; called by muse, mutect2, varscan2
- TP53 | c.690del p.T231Pfs*16 | Frame Shift Del (DEL) | VAF 262/588 reads (45%) | catalogued as CD136735, COSV53715467; called by mutect2, pindel, varscan2
- TRAM1L1 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 64/165 reads (39%) | catalogued as COSV60293477; called by muse, mutect2, varscan2
- TRERF1 | c.2960C>G p.P987R | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs375818850; called by muse, varscan2
- TRIM9 | c.1696C>G p.R566G | Missense Mutation (SNP) | VAF 83/691 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758344911, COSV53618618; called by muse, mutect2, varscan2
- TSGA10 | c.677A>G p.Y226C | Missense Mutation (SNP) | VAF 22/135 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.896); catalogued as rs377151625; called by muse, mutect2, varscan2
- TSR3 | c.52C>G p.R18G | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV50103710; called by muse, mutect2, varscan2
- TSSK1B | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 14/246 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.656); catalogued as rs1199639514; called by muse, mutect2
- UGT1A6 | c.1556A>G p.K519R | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.25); catalogued as rs1559420819; called by muse, mutect2, varscan2
- VAMP3 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 70/352 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs746963670; called by muse, mutect2, varscan2
- WDHD1 | c.1292del p.K431Sfs*36 | Frame Shift Del (DEL) | VAF 75/235 reads (32%) | catalogued as COSV99051873; called by mutect2, pindel, varscan2
- WDR87 | c.4792G>C p.E1598Q | Missense Mutation (SNP) | VAF 66/774 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.474); catalogued as COSV58193029; called by muse, mutect2
- WDR87 | c.3503C>A p.T1168N | Missense Mutation (SNP) | VAF 147/403 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.464); catalogued as COSV58199395; called by muse, mutect2, varscan2
- XPA | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 61/757 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); catalogued as rs1440375480, COSV100910330; called by muse, mutect2
- ZFHX4 | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 96/400 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.121); catalogued as rs772990885; called by muse, mutect2, varscan2
- ZFP82 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 25/195 reads (13%) | catalogued as COSV67564986; called by muse, mutect2, varscan2
- ZNF254 | c.1016G>A p.R339K | Missense Mutation (SNP) | VAF 175/515 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1269331566; called by muse, mutect2, varscan2
- ZNF468 | c.1060C>A p.P354T | Missense Mutation (SNP) | VAF 79/577 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs1235492623; called by muse, mutect2, varscan2
- ZNF473 | c.718C>G p.Q240E | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV54522359; called by muse, mutect2
- ZNF646 | c.3898C>T p.R1300C | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as rs369638183, COSV54923924; called by muse, mutect2, varscan2
- ZNF793 | c.97T>C p.Y33H | Missense Mutation (SNP) | VAF 103/299 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1306160629; called by muse, mutect2, varscan2
- ZRANB3 | c.613C>G p.L205V | Missense Mutation (SNP) | VAF 35/185 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1294445714; called by muse, mutect2, varscan2
- ABCA10 | c.3966-3C>G | Splice Region (SNP) | VAF 47/262 reads (18%) | called by muse, mutect2, varscan2
- ABCA8 | c.4156-1G>A p.X1386_splice | Splice Site (SNP) | VAF 67/399 reads (17%) | called by muse, mutect2, varscan2
- ABCD4 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 12/234 reads (5%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.472); called by muse, mutect2
- ABCF3 | c.874T>A p.Y292N | Missense Mutation (SNP) | VAF 46/293 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABHD17C | c.146_179del p.Q49Pfs*141 | Frame Shift Del (DEL) | VAF 210/332 reads (63%) | called by mutect2, pindel
- AC004922.1 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 76/924 reads (8%) | called by muse, mutect2
- AC004922.1 | c.1319A>T p.E440V | Missense Mutation (SNP) | VAF 75/914 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ACP7 | c.704_714del p.G235Dfs*35 | Frame Shift Del (DEL) | VAF 50/536 reads (9%) | called by mutect2, pindel
- ADGRF5 | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- AGL | c.1571_1581del p.R524Lfs*10 | Frame Shift Del (DEL) | VAF 34/302 reads (11%) | called by mutect2, pindel
- AGTR1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- ALDH16A1 | c.760-6C>G | Splice Region (SNP) | VAF 52/370 reads (14%) | called by muse, mutect2, varscan2
- ALDH4A1 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 138/758 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANGPT1 | c.669_675del p.T224Kfs*4 | Frame Shift Del (DEL) | VAF 62/507 reads (12%) | called by mutect2, pindel
- ANLN | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 50/309 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- APC2 | c.2231dup p.Q745Afs*11 | Frame Shift Ins (INS) | VAF 59/297 reads (20%) | called by mutect2, pindel, varscan2
- APOB | c.6193G>C p.D2065H | Missense Mutation (SNP) | VAF 83/161 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARHGAP29 | c.568_575del p.S190Rfs*11 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | called by pindel, varscan2*
- ARHGEF28 | c.1046A>T p.K349I | Missense Mutation (SNP) | VAF 106/265 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ARID5A | c.411-6_419del p.X137_splice | Splice Site (DEL) | VAF 24/138 reads (17%) | called by mutect2, pindel, varscan2
- ARSK | c.557G>C p.W186S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP6V1E1 | c.172G>C p.E58Q | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- B3GALNT1 | c.920_928del p.A307_H309del | In Frame Del (DEL) | VAF 41/238 reads (17%) | called by mutect2, pindel, varscan2
- BACH1 | c.18C>G p.N6K | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.95); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAZ1A | c.3649G>C p.D1217H | Missense Mutation (SNP) | VAF 78/707 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- BCL7C | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BHMG1 | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 49/409 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- BMP1 | c.1860G>T p.Q620H | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- BTBD19 | c.316_334del p.T106Gfs*5 | Frame Shift Del (DEL) | VAF 42/348 reads (12%) | called by mutect2, pindel
- C12orf66 | c.356A>T p.E119V | Missense Mutation (SNP) | VAF 183/552 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- C16orf71 | c.271C>G p.P91A | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- C22orf15 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 63/505 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- C6orf89 | c.899G>C p.C300S (on ENST00000373685; = p.C307S on NM_152734.4) | Missense Mutation (SNP) | VAF 30/265 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1E | c.834A>C p.E278D | Missense Mutation (SNP) | VAF 74/599 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, varscan2
- CASP10 | c.1256C>A p.P419H (on ENST00000272879 / NM_032974.5; = p.P376H on NM_001230.5) | Missense Mutation (SNP) | VAF 60/285 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC189 | c.366C>A p.D122E | Missense Mutation (SNP) | VAF 143/667 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCR7 | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 77/299 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCR8 | c.753G>T p.W251C | Missense Mutation (SNP) | VAF 40/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK3 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 53/251 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CDK5R2 | c.797T>C p.L266P | Missense Mutation (SNP) | VAF 384/895 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELSR1 | c.5990_6006del p.Q1997Lfs*47 | Frame Shift Del (DEL) | VAF 46/528 reads (9%) | called by mutect2, pindel
- CEP170B | c.4060A>G p.T1354A (on ENST00000453495; = p.T1283A on NM_015005.3) | Missense Mutation (SNP) | VAF 106/739 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CGB1 | c.286C>G p.P96A | Missense Mutation (SNP) | VAF 79/976 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHAF1A | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 51/228 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- CHAMP1 | c.1159C>G p.P387A | Missense Mutation (SNP) | VAF 10/316 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CHST14 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 530/1065 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIP2A | c.2278G>A p.E760K | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CLEC12B | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CLEC17A | c.279T>G p.G93= | Splice Region (SNP) | VAF 66/618 reads (11%) | called by muse, mutect2, varscan2
- CLPTM1 | c.1443G>T p.W481C | Missense Mutation (SNP) | VAF 64/218 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- COL13A1 | c.634C>T p.Q212* (on ENST00000398978 / NM_001130103.2; = p.Q174* on NM_080798.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 86/193 reads (45%) | called by muse, mutect2, varscan2
- COL4A2 | c.2087_2095+33del p.X696_splice | Splice Site (DEL) | VAF 28/336 reads (8%) | called by mutect2, pindel
- COL5A1 | c.3704C>A p.P1235H | Missense Mutation (SNP) | VAF 112/761 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- COL7A1 | c.1308C>G p.N436K | Missense Mutation (SNP) | VAF 318/762 reads (42%) | SIFT tolerated (0.74); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- COL9A1 | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 65/665 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.987); called by muse, mutect2
- COMMD3-BMI1 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 22/270 reads (8%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); called by muse, mutect2
- COQ10B | c.716A>T p.*239Lext*11 | Nonstop Mutation (SNP) | VAF 22/78 reads (28%) | called by muse, mutect2
- CPAMD8 | c.1868A>C p.Q623P (on ENST00000651564; = p.Q576P on NM_015692.5) | Missense Mutation (SNP) | VAF 24/674 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CRYBG1 | c.4769_4775del p.E1590Vfs*22 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | called by mutect2, pindel, varscan2
- CSF3 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- CSMD1 | c.4997_5005del p.G1666_F1668del (on ENST00000520002; = p.G1665_F1667del on NM_033225.6) | In Frame Del (DEL) | VAF 43/185 reads (23%) | called by mutect2, pindel, varscan2
- CSMD1 | c.4632T>G p.S1544R (on ENST00000520002; = p.S1543R on NM_033225.6) | Missense Mutation (SNP) | VAF 73/289 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSMD3 | c.2024G>T p.R675I (on ENST00000297405 / NM_001363185.1; = p.R571I on NM_052900.3) | Missense Mutation (SNP) | VAF 33/312 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CTH | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 44/430 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- CTPS2 | c.408T>G p.N136K | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DDX1 | c.2212A>T p.R738* | Nonsense Mutation (SNP) | VAF 34/178 reads (19%) | called by muse, mutect2, varscan2
- DGKI | c.2399C>G p.S800C | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- DNAAF6 | c.482A>T p.Q161L | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DNAH5 | c.10396G>T p.E3466* | Nonsense Mutation (SNP) | VAF 46/824 reads (6%) | called by muse, mutect2
- DNAH6 | c.5418T>G p.N1806K | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DSP | c.6355G>C p.E2119Q | Missense Mutation (SNP) | VAF 177/542 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- DYNC1I2 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- DYNC2H1 | c.11767G>C p.E3923Q | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.596); called by muse, mutect2
- ENTHD1 | c.249G>T p.K83N | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPB41L5 | c.1276G>C p.V426L | Missense Mutation (SNP) | VAF 72/600 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- EPHX3 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 276/926 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- ETV3 | c.306C>G p.I102M | Missense Mutation (SNP) | VAF 31/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EXPH5 | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 23/90 reads (26%) | called by muse, mutect2, varscan2
- FAM135B | c.2699T>C p.L900P | Missense Mutation (SNP) | VAF 58/282 reads (21%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FAM160A1 | c.380C>G p.T127S | Missense Mutation (SNP) | VAF 70/454 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- FAM205A | c.3538C>A p.P1180T | Missense Mutation (SNP) | VAF 98/234 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- FAM53A | c.518C>A p.A173D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- FAM83E | c.805C>G p.L269V | Missense Mutation (SNP) | VAF 140/937 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FANCA | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 91/376 reads (24%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FASTKD5 | c.998C>T p.S333F | Missense Mutation (SNP) | VAF 78/486 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FBXL3 | c.427G>C p.G143R | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBXO11 | c.265G>A p.E89K (on ENST00000403359 / NM_001190274.2; = p.E5K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/302 reads (16%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FBXO43 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- FBXO7 | c.302A>G p.N101S | Missense Mutation (SNP) | VAF 122/440 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXW4 | c.698C>G p.S233C | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FGF18 | c.269C>G p.T90R | Missense Mutation (SNP) | VAF 157/311 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- FGL2 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 125/564 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- FNDC3A | c.1486G>C p.D496H (on ENST00000492622 / NM_001079673.2; = p.D440H on NM_014923.5) | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- FNIP1 | c.2737G>T p.V913F | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- FRMPD2 | c.1665G>T p.E555D | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- FSIP2 | c.9762del p.F3254Lfs*5 | Frame Shift Del (DEL) | VAF 38/211 reads (18%) | called by mutect2, pindel, varscan2
- GALR3 | c.803C>A p.A268D | Missense Mutation (SNP) | VAF 78/434 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- GBA | c.890A>T p.D297V | Missense Mutation (SNP) | VAF 203/1448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- GPRC5C | c.967C>A p.P323T (on ENST00000652232; = p.P278T on NM_018653.4) | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSG1L2 | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- H4C11 | c.158A>G p.E53G | Missense Mutation (SNP) | VAF 70/513 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.308); called by muse, mutect2, varscan2
- HDAC3 | c.847G>T p.V283F | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- HRH4 | c.83C>T p.A28V | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HSPD1 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 55/435 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- IGSF21 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 80/586 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- KCNB1 | c.1591G>C p.D531H | Missense Mutation (SNP) | VAF 32/234 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KDM5A | c.830dup p.M277Ifs*13 | Frame Shift Ins (INS) | VAF 152/647 reads (23%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.5329A>C p.N1777H | Missense Mutation (SNP) | VAF 58/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0930 | c.853-3C>A | Splice Region (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- KIAA1671 | c.2971C>G p.Q991E | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF1B | c.1684G>C p.D562H (on ENST00000377086 / NM_001365952.1; = p.D516H on NM_015074.3) | Missense Mutation (SNP) | VAF 110/468 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KIF20B | c.2365C>T p.H789Y (on ENST00000371728 / NM_001284259.2; = p.H749Y on NM_016195.4) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KIF3C | c.1135C>G p.L379V | Missense Mutation (SNP) | VAF 58/336 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KLHL12 | c.1171A>T p.R391W | Missense Mutation (SNP) | VAF 71/488 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- KLK9 | c.724G>C p.D242H | Missense Mutation (SNP) | VAF 38/279 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- KMT2D | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 56/247 reads (23%) | called by muse, mutect2, varscan2
- KNL1 | c.796G>C p.E266Q (on ENST00000346991 / NM_170589.5; = p.E240Q on NM_144508.5) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- KNSTRN | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KSR2 | c.2193C>A p.S731R | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- LDHA | c.902C>G p.S301* | Nonsense Mutation (SNP) | VAF 49/209 reads (23%) | called by muse, mutect2, varscan2
- LENG9 | c.257C>T p.S86L | Missense Mutation (SNP) | VAF 251/560 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- LETM1 | c.608_619del p.C203_L206del | In Frame Del (DEL) | VAF 46/232 reads (20%) | called by mutect2, pindel
- LHX6 | c.191C>G p.S64C (on ENST00000373755 / NM_001242334.2; = p.S93C on NM_014368.5) | Missense Mutation (SNP) | VAF 52/314 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- LIMK1 | c.1380_1384del p.D460Efs*17 | Frame Shift Del (DEL) | VAF 44/190 reads (23%) | called by mutect2, pindel, varscan2
- LRRC32 | c.775C>A p.P259T | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY6G6F-LY6G6D | c.383G>C p.G128A | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MALT1 | c.1533T>G p.F511L | Missense Mutation (SNP) | VAF 73/202 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAN1B1 | c.352G>C p.E118Q | Missense Mutation (SNP) | VAF 104/652 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAP1A | c.2710G>T p.D904Y | Missense Mutation (SNP) | VAF 186/512 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAP3K14 | c.2779G>T p.A927S | Missense Mutation (SNP) | VAF 68/346 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAP4K3 | c.2012G>C p.W671S | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.071); called by muse, mutect2
- MCM7 | c.921C>A p.N307K | Missense Mutation (SNP) | VAF 90/525 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MDM4 | c.1063G>C p.E355Q | Missense Mutation (SNP) | VAF 159/318 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MEGF8 | c.7622G>A p.G2541D (on ENST00000251268 / NM_001271938.2; = p.G2474D on NM_001410.3) | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MEGF8 | c.8464G>A p.G2822S (on ENST00000251268 / NM_001271938.2; = p.G2755S on NM_001410.3) | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MMP17 | c.1697G>C p.G566A | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2, varscan2
- MRC1 | c.2842G>T p.G948C | Missense Mutation (SNP) | VAF 107/536 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MTHFD2L | c.499G>C p.D167H (on ENST00000395759 / NM_001144978.2; = p.D109H on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTMR14 | c.1337_1340delinsCT p.F446Sfs*17 | Frame Shift Del (DEL) | VAF 85/630 reads (13%) | called by pindel, varscan2*
- MTMR6 | c.1217_1222del p.H406_T408delinsP | In Frame Del (DEL) | VAF 37/380 reads (10%) | called by mutect2, pindel*
- MUC2 | c.3711C>G p.F1237L | Missense Mutation (SNP) | VAF 88/412 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYH2 | c.3175A>T p.R1059W | Missense Mutation (SNP) | VAF 130/287 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NARF | c.142_152del p.I48Rfs*6 | Frame Shift Del (DEL) | VAF 19/138 reads (14%) | called by mutect2, pindel, varscan2
- NDUFA12 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 169/1005 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- NEB | c.18043_18049del p.L6015Wfs*8 | Frame Shift Del (DEL) | VAF 40/266 reads (15%) | called by mutect2, pindel, varscan2
- NFE2L2 | c.338_342del p.A113Vfs*3 | Frame Shift Del (DEL) | VAF 60/416 reads (14%) | called by mutect2, pindel, varscan2
- NLRP1 | c.3382G>C p.E1128Q | Missense Mutation (SNP) | VAF 112/667 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NME1-NME2 | c.56C>G p.S19* | Nonsense Mutation (SNP) | VAF 50/211 reads (24%) | called by muse, mutect2, varscan2
- NOL4L | c.598G>C p.E200Q | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NRIP1 | c.2903A>G p.N968S | Missense Mutation (SNP) | VAF 82/171 reads (48%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN1 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUCB2 | c.112C>T p.H38Y | Missense Mutation (SNP) | VAF 58/265 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- NUP210L | c.1600T>G p.F534V | Missense Mutation (SNP) | VAF 48/305 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- OGFRL1 | c.952G>C p.E318Q | Missense Mutation (SNP) | VAF 43/321 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OR2AE1 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 72/355 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- P2RY12 | c.685G>T p.V229F | Missense Mutation (SNP) | VAF 31/214 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.218); called by muse, mutect2, varscan2
- PABPC5 | c.202T>G p.F68V | Missense Mutation (SNP) | VAF 57/140 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- PDCL3 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PKP3 | c.100_137del p.E34Pfs*22 | Frame Shift Del (DEL) | VAF 74/618 reads (12%) | called by mutect2, pindel
- PLA2G4A | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 62/403 reads (15%) | called by muse, mutect2, varscan2
- PLAA | c.1238G>C p.G413A | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- PLCB1 | c.3418C>A p.P1140T | Missense Mutation (SNP) | VAF 23/211 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCH1 | c.4583_4627del p.G1528_T1543delinsA (on ENST00000340059 / NM_001130960.2; = p.G1520_T1535delinsA on NM_014996.4 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 64/494 reads (13%) | called by mutect2, pindel
- PLPP2 | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 18/464 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2
- POLR3B | c.2818-2A>G p.X940_splice | Splice Site (SNP) | VAF 27/454 reads (6%) | called by muse, mutect2
- PRCD | c.120_143+11del p.X40_splice | Splice Site (DEL) | VAF 72/471 reads (15%) | called by mutect2, pindel
- PREP | c.261C>G p.I87M (on ENST00000369110; = p.I153M on NM_002726.5) | Missense Mutation (SNP) | VAF 183/679 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PRKCB | c.567T>A p.N189K | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- PSMD8 | c.210C>A p.N70K | Missense Mutation (SNP) | VAF 278/714 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPN21 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PTPRF | c.4379G>T p.C1460F | Missense Mutation (SNP) | VAF 39/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRZ1 | c.5085T>G p.D1695E | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- R3HCC1 | c.1264C>G p.L422V (on ENST00000411463; = p.L382V on NM_001136108.3) | Missense Mutation (SNP) | VAF 140/402 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RAG1 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- RANBP2 | c.8726A>G p.D2909G | Missense Mutation (SNP) | VAF 70/267 reads (26%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- RGS6 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 15/240 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- RMDN1 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2
- ROCK2 | c.1638A>T p.R546S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ROS1 | c.1669C>G p.L557V | Missense Mutation (SNP) | VAF 90/443 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RREB1 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RRM2B | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 87/598 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RRM2B | c.173A>C p.Q58P | Missense Mutation (SNP) | VAF 87/600 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- RTL1 | c.3099A>C p.E1033D | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCAF11 | c.1966G>C p.D656H | Missense Mutation (SNP) | VAF 55/164 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2
- SCN1A | c.3833C>G p.T1278R (on ENST00000303395 / NM_001202435.3; = p.T1267R on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/338 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SCRN2 | c.539C>G p.A180G | Missense Mutation (SNP) | VAF 83/352 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SEMA6D | c.1766A>T p.D589V | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SERAC1 | c.103A>C p.K35Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- SGO1 | c.1628T>G p.V543G (on ENST00000263753 / NM_001012410.5; = p.V274G on NM_138484.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/150 reads (23%) | PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SHANK2 | c.3631G>C p.D1211H | Missense Mutation (SNP) | VAF 110/1616 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SIM1 | c.1835C>G p.P612R | Missense Mutation (SNP) | VAF 147/427 reads (34%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SIX5 | c.445_446del p.S149Pfs*22 | Frame Shift Del (DEL) | VAF 91/446 reads (20%) | called by pindel, varscan2
- SLC13A3 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- SLC30A5 | c.1231C>A p.L411I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- SLC34A1 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 107/226 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- SLC34A2 | c.1282T>A p.F428I | Missense Mutation (SNP) | VAF 144/725 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SLC45A4 | c.1717G>A p.A573T (on ENST00000517878 / NM_001286646.2; = p.A522T on NM_001080431.2) | Missense Mutation (SNP) | VAF 85/404 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SLC8A2 | c.829_834del p.P277_K278del | In Frame Del (DEL) | VAF 39/372 reads (10%) | called by mutect2, pindel
- SLC9C1 | c.2398G>C p.E800Q | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- SORL1 | c.5458G>T p.A1820S | Missense Mutation (SNP) | VAF 66/271 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- SPAG9 | c.2596C>G p.P866A (on ENST00000262013 / NM_001130528.3; = p.P852A on NM_003971.6) | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.206); called by muse, mutect2
- SPARC | c.889_908del p.I297Lfs*40 | Frame Shift Del (DEL) | VAF 11/105 reads (10%) | called by mutect2, pindel
- SPATA31A1 | c.3857G>C p.R1286T | Missense Mutation (SNP) | VAF 106/796 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.785); called by mutect2, varscan2
- SPATA31A6 | c.3845G>C p.R1282T | Missense Mutation (SNP) | VAF 256/894 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.963); called by muse, varscan2
- SPRED3 | c.815C>A p.A272D | Missense Mutation (SNP) | VAF 37/306 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SPTBN4 | c.4186G>C p.E1396Q | Missense Mutation (SNP) | VAF 92/713 reads (13%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SQSTM1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 179/459 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ST3GAL5 | c.343G>A p.E115K (on ENST00000377332; = p.E155K on NM_003896.4) | Missense Mutation (SNP) | VAF 88/484 reads (18%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- STAG1 | c.3234G>C p.K1078N | Missense Mutation (SNP) | VAF 87/527 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- SUPT3H | c.250C>G p.R84G (on ENST00000371460 / NM_181356.3; = p.R73G on NM_003599.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 48/301 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SYTL1 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 59/265 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SZT2 | c.9077C>G p.S3026C (on ENST00000634258 / NM_001365999.1; = p.S2969C on NM_015284.4) | Missense Mutation (SNP) | VAF 58/378 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1L | c.3335A>T p.E1112V | Missense Mutation (SNP) | VAF 50/347 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TAF1L | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 49/346 reads (14%) | called by muse, mutect2, varscan2
- TANC1 | c.2530_2541del p.A844_F847del | In Frame Del (DEL) | VAF 92/234 reads (39%) | called by mutect2, pindel, varscan2
- TCIRG1 | c.1065_1088del p.D356_R363del | In Frame Del (DEL) | VAF 248/1418 reads (17%) | called by mutect2, pindel
- TDRD9 | c.1587T>G p.C529W | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TIPIN | c.208C>G p.Q70E | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TLL1 | c.1705G>A p.A569T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- TLR6 | c.1671_1685del p.S558_D562del | In Frame Del (DEL) | VAF 56/384 reads (15%) | called by mutect2, varscan2
- TMIE | c.457_460del p.K153Efs*29 | Frame Shift Del (DEL) | VAF 78/452 reads (17%) | called by mutect2, pindel, varscan2
- TNFRSF4 | c.646G>T p.A216S | Missense Mutation (SNP) | VAF 132/418 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- TNKS2 | c.2097_2109del p.Q700Mfs*2 | Frame Shift Del (DEL) | VAF 24/232 reads (10%) | called by mutect2, pindel
- TNNT2 | c.703A>C p.N235H (on ENST00000236918; = p.N232H on NM_000364.4) | Missense Mutation (SNP) | VAF 329/596 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TPR | c.4297C>G p.Q1433E | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- TRIM52 | c.814-3_819del p.X272_splice | Splice Site (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- TRMT10C | c.488T>C p.I163T | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM3 | c.463G>T p.A155S (on ENST00000357533 / NM_001366142.2; = p.A124S on NM_001007471.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- TTC28 | c.6017C>G p.S2006C | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTC6 | c.1217C>G p.S406* (on ENST00000267368; = p.S1772* on NM_001310135.3) | Nonsense Mutation (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
- TTC6 | c.1331_1334del p.E444Afs*19 (on ENST00000267368; = p.E1810Afs*19 on NM_001310135.3) | Frame Shift Del (DEL) | VAF 19/197 reads (10%) | called by mutect2, pindel*
- TTN | c.48523G>C p.E16175Q (on ENST00000591111; = p.E8751Q on NM_003319.4) | Missense Mutation (SNP) | VAF 42/459 reads (9%) | PolyPhen possibly damaging (0.603); called by muse, mutect2
- TTN | c.5680A>T p.I1894F (on ENST00000591111; = p.I1848F on NM_003319.4) | Missense Mutation (SNP) | VAF 156/608 reads (26%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TUFM | c.272A>C p.K91T | Missense Mutation (SNP) | VAF 116/624 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- UBE2O | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 146/563 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- UBE2QL1 | c.472G>T p.V158L | Missense Mutation (SNP) | VAF 73/124 reads (59%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2T | c.75G>C p.W25C | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- UBE3C | c.1589G>C p.R530T | Missense Mutation (SNP) | VAF 65/216 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- UMPS | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 51/314 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.2932G>A p.A978T | Missense Mutation (SNP) | VAF 47/225 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP11 | c.155C>A p.A52D (on ENST00000218348; = p.A9D on NM_001371072.1) | Missense Mutation (SNP) | VAF 155/362 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.207); called by muse, mutect2, varscan2
- USP42 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VAMP3 | c.2+1G>T p.X1_splice | Splice Site (SNP) | VAF 71/350 reads (20%) | called by muse, mutect2, varscan2
- VPS51 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 87/571 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR54 | c.138C>G p.S46R | Missense Mutation (SNP) | VAF 91/754 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- WDR6 | c.2713G>A p.E905K | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- WIPI1 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 67/216 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- YTHDF3 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- YWHAQ | c.477G>C p.E159D | Missense Mutation (SNP) | VAF 58/237 reads (24%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB24 | c.1411T>C p.F471L | Missense Mutation (SNP) | VAF 53/246 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZC3H11A | c.710C>G p.S237* | Nonsense Mutation (SNP) | VAF 73/249 reads (29%) | called by muse, mutect2, varscan2
- ZC3H4 | c.773G>C p.G258A | Missense Mutation (SNP) | VAF 39/274 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFYVE27 | c.424C>G p.R142G | Missense Mutation (SNP) | VAF 26/460 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- ZKSCAN1 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 26/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF16 | c.1951C>G p.H651D | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF229 | c.616C>G p.L206V | Missense Mutation (SNP) | VAF 42/308 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ZNF407 | c.5652G>C p.E1884D | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ZNF430 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 81/608 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF469 | c.11634G>T p.K3878N (on ENST00000437464; = p.K3906N on NM_001367624.2) | Missense Mutation (SNP) | VAF 114/440 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- ZNF471 | c.1096A>G p.R366G | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF512B | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 68/256 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF579 | c.919T>C p.F307L | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF585B | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 65/578 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF655 | c.331_341del p.R111Afs*12 | Frame Shift Del (DEL) | VAF 26/211 reads (12%) | called by mutect2, pindel, varscan2
- ZNF726 | c.1962+8G>T | Splice Region (SNP) | VAF 43/290 reads (15%) | called by muse, mutect2, varscan2
- ZNF761 | c.634G>C p.E212Q | Missense Mutation (SNP) | VAF 69/515 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ZNF808 | c.2583C>G p.H861Q | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.021); called by muse, mutect2
- ZNF853 | c.1369G>C p.V457L | Missense Mutation (SNP) | VAF 74/357 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZRANB1 | c.578C>G p.S193* | Nonsense Mutation (SNP) | VAF 67/269 reads (25%) | called by muse, mutect2, varscan2
- ZSWIM2 | c.165+8C>A | Splice Region (SNP) | VAF 34/236 reads (14%) | called by muse, mutect2, varscan2
- ABCF2 | c.168G>A p.L56= | Silent (SNP) | VAF 120/540 reads (22%) | called by muse, mutect2, varscan2
- ACACA | c.5005C>T p.L1669= | Silent (SNP) | VAF 348/799 reads (44%) | called by muse, mutect2, varscan2
- ACRBP | c.1293G>T p.L431= | Silent (SNP) | VAF 71/300 reads (24%) | called by muse, mutect2, varscan2
- ACSS3 | c.1179A>C p.A393= | Silent (SNP) | VAF 80/270 reads (30%) | called by muse, mutect2, varscan2
- ADCY1 | c.216G>C p.A72= | Silent (SNP) | VAF 264/541 reads (49%) | called by muse, mutect2, varscan2
- AKR1C4 | c.939C>T p.D313= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as rs1383503952; called by muse, mutect2, varscan2
- ALDH8A1 | c.1329C>G p.V443= | Silent (SNP) | VAF 197/602 reads (33%) | called by muse, mutect2, varscan2
- ANK2 | c.5373C>G p.V1791= | Silent (SNP) | VAF 44/203 reads (22%) | called by muse, mutect2, varscan2
- ANKRD26 | c.4137T>C p.N1379= | Silent (SNP) | VAF 39/85 reads (46%) | called by muse, mutect2, varscan2
- ANKRD53 | c.441C>T p.A147= | Silent (SNP) | VAF 57/450 reads (13%) | catalogued as rs373055320; called by muse, mutect2, varscan2
- AP002748.5 | c.708C>G p.V236= | Silent (SNP) | VAF 178/881 reads (20%) | catalogued as rs1385052420, COSV59151474, COSV59152697; called by muse, mutect2, varscan2
- AP3M2 | c.906G>A p.G302= | Silent (SNP) | VAF 85/422 reads (20%) | catalogued as rs748831005; called by muse, varscan2
- ARL6IP4 | c.435T>A p.L145= | Silent (SNP) | VAF 101/209 reads (48%) | called by muse, mutect2, varscan2
- ATP6V0A2 | c.1362C>G p.L454= | Silent (SNP) | VAF 102/539 reads (19%) | called by muse, mutect2, varscan2
- ATP6V1E2 | c.300G>A p.L100= | Silent (SNP) | VAF 69/496 reads (14%) | called by muse, mutect2, varscan2
- AUH | c.135G>C p.A45= | Silent (SNP) | VAF 102/600 reads (17%) | called by muse, varscan2
- BPIFC | c.552T>A p.A184= | Silent (SNP) | VAF 24/211 reads (11%) | called by muse, mutect2, varscan2
- BUB1B | c.2808G>T p.L936= | Silent (SNP) | VAF 85/518 reads (16%) | called by muse, mutect2, varscan2
- C12orf42 | c.816C>G p.P272= | Silent (SNP) | VAF 114/663 reads (17%) | called by muse, mutect2, varscan2
- C1orf185 | c.582A>G p.V194= | Silent (SNP) | VAF 8/91 reads (9%) | catalogued as rs1247332922; called by muse, mutect2
- C3orf22 | c.318G>C p.L106= | Silent (SNP) | VAF 58/309 reads (19%) | called by muse, varscan2
- C4orf54 | c.3414G>C p.L1138= | Silent (SNP) | VAF 53/283 reads (19%) | called by muse, mutect2, varscan2
- CD22 | c.2385T>G p.T795= | Silent (SNP) | VAF 195/558 reads (35%) | called by muse, varscan2
- CDC20B | c.1164C>T p.A388= | Silent (SNP) | VAF 173/518 reads (33%) | catalogued as rs759621766; called by muse, mutect2, varscan2
- CGNL1 | c.2862G>A p.Q954= | Silent (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- CHD3 | c.1125G>A p.E375= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2, varscan2
- CHD6 | c.4239G>T p.L1413= | Silent (SNP) | VAF 116/462 reads (25%) | called by muse, mutect2, varscan2
- CLBA1 | c.432C>G p.L144= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as COSV101120951; called by muse, mutect2, varscan2
- COL16A1 | c.420G>A p.R140= | Silent (SNP) | VAF 71/284 reads (25%) | called by muse, mutect2, varscan2
- CPSF1 | c.1800C>T p.F600= | Silent (SNP) | VAF 165/569 reads (29%) | catalogued as rs201246127; called by muse, mutect2, varscan2
- CRYM | c.909C>G p.A303= | Silent (SNP) | VAF 71/473 reads (15%) | called by muse, mutect2, varscan2
- DCAF4 | c.360G>A p.R120= | Silent (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
- DEPDC4 | c.381A>G p.L127= | Silent (SNP) | VAF 21/138 reads (15%) | called by muse, mutect2, varscan2
- DPP6 | c.1509G>C p.L503= (on ENST00000377770 / NM_001364500.2; = p.L441= on NM_001936.5) | Silent (SNP) | VAF 23/168 reads (14%) | called by muse, mutect2, varscan2
- EDEM3 | c.54A>G p.R18= | Silent (SNP) | VAF 70/490 reads (14%) | catalogued as rs761346445; called by muse, varscan2
- EEF2KMT | c.234C>T p.I78= | Silent (SNP) | VAF 116/698 reads (17%) | catalogued as COSV101435295; called by muse, varscan2
- ESPN | c.240C>T p.T80= | Silent (SNP) | VAF 168/1074 reads (16%) | catalogued as rs1394364164; called by muse, mutect2, varscan2
- FBXW12 | c.837C>G p.L279= | Silent (SNP) | VAF 68/377 reads (18%) | called by muse, mutect2, varscan2
- FGF3 | c.42C>G p.P14= | Silent (SNP) | VAF 256/2544 reads (10%) | called by muse, varscan2
- FUT3 | c.390G>A p.Q130= | Silent (SNP) | VAF 18/611 reads (3%) | catalogued as rs1460351315; called by muse, mutect2
- GABRD | c.1266C>T p.I422= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as rs376403451; called by muse, mutect2, varscan2
- GRM7 | c.1239C>T p.D413= | Silent (SNP) | VAF 146/332 reads (44%) | catalogued as rs773679767, COSV63144701; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSTO2 | c.414A>G p.R138= | Silent (SNP) | VAF 115/263 reads (44%) | called by muse, mutect2, varscan2
- H1-2 | c.129C>T p.L43= | Silent (SNP) | VAF 90/534 reads (17%) | catalogued as rs368497302; called by muse, mutect2, varscan2
- HS3ST3B1 | c.339G>A p.E113= | Silent (SNP) | VAF 55/460 reads (12%) | catalogued as COSV100714419; called by muse, mutect2, varscan2
- JAG1 | c.3432C>A p.S1144= | Silent (SNP) | VAF 74/532 reads (14%) | called by muse, mutect2, varscan2
- KLB | c.1416C>T p.Y472= | Silent (SNP) | VAF 41/277 reads (15%) | called by muse, mutect2, varscan2
- LAG3 | c.951C>A p.T317= | Silent (SNP) | VAF 97/550 reads (18%) | called by muse, mutect2, varscan2
- LNX2 | c.2007C>A p.P669= | Silent (SNP) | VAF 43/323 reads (13%) | catalogued as rs140619257, COSV60334919; called by muse, mutect2, varscan2
- LPA | c.2607C>T p.G869= | Silent (SNP) | VAF 176/1029 reads (17%) | called by muse, mutect2, varscan2
- LRCH4 | c.357C>T p.L119= | Silent (SNP) | VAF 17/551 reads (3%) | called by muse, mutect2
- LRFN3 | c.276G>C p.R92= | Silent (SNP) | VAF 83/571 reads (15%) | called by muse, mutect2, varscan2
- LRRC32 | c.1524G>A p.V508= | Silent (SNP) | VAF 96/371 reads (26%) | called by muse, mutect2, varscan2
- MAP3K8 | c.1221G>A p.E407= | Silent (SNP) | VAF 15/495 reads (3%) | called by muse, mutect2
- MAST1 | c.2649T>A p.V883= | Silent (SNP) | VAF 25/212 reads (12%) | called by muse, mutect2, varscan2
- MPHOSPH10 | c.54C>T p.V18= | Silent (SNP) | VAF 54/546 reads (10%) | catalogued as rs1228560402; called by muse, mutect2
- MUC16 | c.28299A>C p.P9433= | Silent (SNP) | VAF 68/310 reads (22%) | called by muse, mutect2, varscan2
- MUC6 | c.1671G>A p.L557= | Silent (SNP) | VAF 44/283 reads (16%) | called by muse, mutect2, varscan2
- MYO16 | c.822C>G p.L274= | Silent (SNP) | VAF 174/316 reads (55%) | called by muse, mutect2, varscan2
- MYOM3 | c.2604A>G p.P868= | Silent (SNP) | VAF 64/278 reads (23%) | called by muse, mutect2, varscan2
- NCAN | c.942G>A p.V314= | Silent (SNP) | VAF 176/687 reads (26%) | called by muse, mutect2, varscan2
- NF1 | c.180T>C p.T60= | Silent (SNP) | VAF 108/311 reads (35%) | called by muse, mutect2, varscan2
- NFE2L2 | c.660G>T p.L220= | Silent (SNP) | VAF 41/140 reads (29%) | called by muse, mutect2, varscan2
- NHS | c.2061C>T p.D687= | Silent (SNP) | VAF 42/122 reads (34%) | called by muse, mutect2, varscan2
- NLRP2 | c.3039C>G p.L1013= | Silent (SNP) | VAF 115/1026 reads (11%) | called by muse, mutect2, varscan2
- NRXN2 | c.4410C>T p.R1470= | Silent (SNP) | VAF 155/400 reads (39%) | called by muse, mutect2, varscan2
- OPRL1 | c.357G>C p.G119= | Silent (SNP) | VAF 70/533 reads (13%) | called by muse, mutect2, varscan2
- OR1N1 | c.669C>A p.I223= | Silent (SNP) | VAF 60/309 reads (19%) | called by muse, mutect2, varscan2
- PASK | c.655A>C p.R219= | Silent (SNP) | VAF 97/397 reads (24%) | called by muse, mutect2, varscan2
- PIK3C2A | c.3744C>T p.I1248= | Silent (SNP) | VAF 35/216 reads (16%) | called by muse, mutect2, varscan2
- PMFBP1 | c.1500G>A p.L500= (on ENST00000537465; = p.L495= on NM_031293.3) | Silent (SNP) | VAF 10/202 reads (5%) | catalogued as rs1378027557; called by muse, mutect2
- PNMA5 | c.1251G>A p.Q417= | Silent (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- POLR2K | c.144G>A p.R48= | Silent (SNP) | VAF 29/175 reads (17%) | called by muse, mutect2, varscan2
- PRDM16 | c.2373C>A p.G791= | Silent (SNP) | VAF 45/120 reads (38%) | called by muse, mutect2, varscan2
- PRPF8 | c.4368A>C p.T1456= | Silent (SNP) | VAF 144/714 reads (20%) | called by muse, mutect2, varscan2
- PTPN14 | c.2439G>C p.L813= | Silent (SNP) | VAF 53/283 reads (19%) | called by muse, mutect2, varscan2
- RP1 | c.1788C>T p.D596= | Silent (SNP) | VAF 54/194 reads (28%) | catalogued as rs977291091; called by muse, mutect2, varscan2
- RPL35 | c.147C>G p.V49= | Silent (SNP) | VAF 51/395 reads (13%) | catalogued as rs1223602535; called by muse, mutect2, varscan2
- RRP1 | c.1146G>A p.P382= | Silent (SNP) | VAF 52/204 reads (25%) | catalogued as rs763176941; called by muse, mutect2, varscan2
- SEMA5A | c.1809G>A p.S603= | Silent (SNP) | VAF 152/547 reads (28%) | catalogued as rs1426385046, COSV66801974; called by muse, mutect2, varscan2
- SEZ6 | c.2544C>A p.A848= | Silent (SNP) | VAF 64/361 reads (18%) | called by muse, mutect2, varscan2
- SLC35B1 | c.972C>G p.L324= (on ENST00000649906; = p.L287= on NM_005827.4) | Silent (SNP) | VAF 54/263 reads (21%) | called by muse, mutect2, varscan2
- SMARCD1 | c.945C>T p.I315= | Silent (SNP) | VAF 84/247 reads (34%) | called by muse, mutect2, varscan2
- SNX18 | c.150C>G p.L50= | Silent (SNP) | VAF 46/279 reads (16%) | called by muse, mutect2, varscan2
- SP8 | c.132C>T p.C44= (on ENST00000361443 / NM_198956.4; = p.C62= on NM_182700.6) | Silent (SNP) | VAF 153/850 reads (18%) | called by muse, mutect2, varscan2
- SPATA7 | c.1617T>C p.N539= | Silent (SNP) | VAF 33/157 reads (21%) | called by muse, mutect2, varscan2
- SPRYD7 | c.590G>A p.*197= | Silent (SNP) | VAF 63/125 reads (50%) | called by muse, mutect2, varscan2
- SRCIN1 | c.1959G>A p.R653= (on ENST00000621492; = p.R619= on NM_025248.3) | Silent (SNP) | VAF 153/337 reads (45%) | called by muse, mutect2, varscan2
- SYNE1 | c.17208T>G p.A5736= (on ENST00000367255 / NM_182961.4; = p.A5665= on NM_033071.3) | Silent (SNP) | VAF 81/244 reads (33%) | called by muse, mutect2, varscan2
- TGFBI | c.66G>A p.L22= | Silent (SNP) | VAF 247/722 reads (34%) | catalogued as rs1460124781; called by muse, mutect2, varscan2
- TLE1 | c.870G>A p.T290= | Silent (SNP) | VAF 47/327 reads (14%) | catalogued as rs755701794; called by muse, mutect2, varscan2
- TLE3 | c.1770C>G p.V590= | Silent (SNP) | VAF 68/434 reads (16%) | called by muse, mutect2, varscan2
- TMEM178A | c.561C>T p.V187= | Silent (SNP) | VAF 31/291 reads (11%) | called by muse, mutect2, varscan2
- TTC3 | c.5961T>A p.L1987= | Silent (SNP) | VAF 140/632 reads (22%) | called by muse, mutect2, varscan2
- TTN | c.96801T>A p.A32267= (on ENST00000591111; = p.A24843= on NM_003319.4) | Silent (SNP) | VAF 28/227 reads (12%) | called by muse, mutect2, varscan2
- TUBGCP4 | c.141G>A p.R47= | Silent (SNP) | VAF 46/312 reads (15%) | called by muse, mutect2, varscan2
- USP31 | c.438C>T p.L146= | Silent (SNP) | VAF 51/325 reads (16%) | catalogued as rs1433107319, COSV54854666; called by muse, mutect2, varscan2
- ZBTB46 | c.660C>T p.D220= | Silent (SNP) | VAF 68/317 reads (21%) | catalogued as rs202192767, COSV99829851; called by muse, mutect2, varscan2
- ZER1 | c.471C>T p.L157= | Silent (SNP) | VAF 83/582 reads (14%) | catalogued as rs773875900; called by muse, mutect2, varscan2
- ZNF112 | c.540T>C p.H180= (on ENST00000337401 / NM_001083335.2; = p.H174= on NM_013380.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/355 reads (10%) | called by muse, mutect2, varscan2
- ZNF132 | c.1731G>A p.G577= | Silent (SNP) | VAF 43/307 reads (14%) | called by muse, mutect2, varscan2
- ZNF597 | c.492C>T p.N164= | Silent (SNP) | VAF 56/373 reads (15%) | called by muse, mutect2, varscan2
- ZNF597 | c.114C>G p.L38= | Silent (SNP) | VAF 57/373 reads (15%) | catalogued as COSV57084705; called by muse, mutect2, varscan2
- ZNF771 | c.510G>C p.T170= | Silent (SNP) | VAF 104/707 reads (15%) | called by muse, mutect2, varscan2
- AC002519.1 | chr16:31793366 A>G | 3'Flank (SNP) | VAF 23/141 reads (16%) | called by muse, mutect2, varscan2
- AC006288.1 | n.277C>A | RNA (SNP) | VAF 27/240 reads (11%) | called by muse, mutect2, varscan2
- AC092675.1 | n.459-141C>T | Intron (SNP) | VAF 49/330 reads (15%) | called by muse, mutect2, varscan2
- AL078621.1 | chr2:113601250 C>G | 3'Flank (SNP) | VAF 82/854 reads (10%) | called by muse, varscan2
- AL356753.1 | n.420G>C | RNA (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179368G>C | Intron (SNP) | VAF 28/180 reads (16%) | called by muse, varscan2
- ATP2A1 | c.1096-1762T>C | Intron (SNP) | VAF 21/109 reads (19%) | called by muse, mutect2, varscan2
- ATP5PF | c.*60A>G | 3'UTR (SNP) | VAF 19/109 reads (17%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29715454 A>C | 5'Flank (SNP) | VAF 24/174 reads (14%) | called by muse, mutect2, varscan2
- CA6 | c.259+2095C>T | Intron (SNP) | VAF 39/570 reads (7%) | called by muse, mutect2
- CACNA1H | c.4759+23G>A | Intron (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- CCDC159 | c.22-675C>G | Intron (SNP) | VAF 75/309 reads (24%) | called by muse, mutect2, varscan2
- CCN5 | c.*78G>C | 3'UTR (SNP) | VAF 13/63 reads (21%) | called by muse, mutect2, varscan2
- CHD4 | c.4642+64C>T | Intron (SNP) | VAF 51/272 reads (19%) | called by muse, mutect2, varscan2
- CHIT1 | c.*629C>T | 3'UTR (SNP) | VAF 100/703 reads (14%) | called by muse, mutect2, varscan2
- CREB3L1 | c.*149T>C | 3'UTR (SNP) | VAF 22/81 reads (27%) | called by muse, mutect2, varscan2
- CREB3L3 | c.577-7dup | Intron (INS) | VAF 109/612 reads (18%) | catalogued as rs775056463; called by mutect2, pindel, varscan2
- CTIF | c.*30G>T | 3'UTR (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- CUL7 | c.2863-48C>G | Intron (SNP) | VAF 106/524 reads (20%) | called by muse, mutect2, varscan2
- DYRK4 | c.133-8079A>G | Intron (SNP) | VAF 29/260 reads (11%) | called by muse, mutect2, varscan2
- EHD4 | chr15:41895276 T>C | 3'Flank (SNP) | VAF 112/197 reads (57%) | called by muse, mutect2, varscan2
- EMC2 | c.-4G>A | 5'UTR (SNP) | VAF 63/349 reads (18%) | called by muse, mutect2, varscan2
- EPHA6 | c.2784+8145C>G | Intron (SNP) | VAF 42/207 reads (20%) | called by muse, mutect2, varscan2
- ERVV-1 | chr19:53010126 A>T | 5'Flank (SNP) | VAF 42/329 reads (13%) | called by muse, mutect2, varscan2
- FAM74A3 | n.68A>G | RNA (SNP) | VAF 111/501 reads (22%) | called by muse, mutect2, varscan2
- GABRP | c.1020+293_1020+297del | Intron (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- GALNT9 | c.1077+7310C>T | Intron (SNP) | VAF 73/350 reads (21%) | catalogued as rs115283014; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593272 C>T | 3'Flank (SNP) | VAF 62/435 reads (14%) | called by muse, mutect2, varscan2
- GNB1 | c.-15C>G | 5'UTR (SNP) | VAF 36/221 reads (16%) | called by muse, mutect2, varscan2
- GRIK3 | c.2565+48G>A | Intron (SNP) | VAF 20/115 reads (17%) | catalogued as rs763884917, COSV66137571; called by muse, mutect2
- GSTM2 | c.*25G>T | 3'UTR (SNP) | VAF 69/517 reads (13%) | called by muse, mutect2, varscan2
- HERC2P3 | n.1281G>A | RNA (SNP) | VAF 105/1068 reads (10%) | catalogued as rs755520006; called by muse, mutect2, varscan2
- HMGN2P46 | n.852A>C | RNA (SNP) | VAF 50/344 reads (15%) | called by muse, mutect2, varscan2
- IMPG1 | c.562+215C>A | Intron (SNP) | VAF 8/76 reads (11%) | called by muse, mutect2
- KAT6B | c.3664+15G>A | Intron (SNP) | VAF 36/251 reads (14%) | catalogued as rs766221178; called by muse, mutect2, varscan2
- KCNAB2 | c.*1401G>C | 3'UTR (SNP) | VAF 48/202 reads (24%) | called by muse, mutect2, varscan2
- KHSRP | c.*671G>C | 3'UTR (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- KRT87P | n.957G>C | RNA (SNP) | VAF 59/357 reads (17%) | called by muse, mutect2, varscan2
- LGALS8 | c.550-81C>G | Intron (SNP) | VAF 81/544 reads (15%) | called by muse, mutect2, varscan2
- LINC01119 | n.1621G>C | RNA (SNP) | VAF 49/418 reads (12%) | called by muse, mutect2, varscan2
- LMO1 | chr11:8268485 A>G | 5'Flank (SNP) | VAF 46/215 reads (21%) | called by muse, mutect2, varscan2
- LYST | c.8358+2807C>T | Intron (SNP) | VAF 51/340 reads (15%) | called by muse, mutect2, varscan2
- MAP4 | c.2000-14724G>T | Intron (SNP) | VAF 58/359 reads (16%) | called by muse, mutect2, varscan2
- MGAM | c.4619-2019C>A | Intron (SNP) | VAF 66/350 reads (19%) | called by muse, mutect2, varscan2
- MINPP1 | c.638-137A>G | Intron (SNP) | VAF 38/246 reads (15%) | catalogued as rs776238381; called by muse, mutect2, varscan2
- MMS19 | c.-8-9G>C | Intron (SNP) | VAF 83/357 reads (23%) | called by muse, mutect2, varscan2
- MRPL20 | chr1:1399664 G>A | 3'Flank (SNP) | VAF 91/597 reads (15%) | catalogued as rs1319055882; called by muse, mutect2, varscan2
- MTHFD1 | c.1884+32G>A | Intron (SNP) | VAF 78/481 reads (16%) | called by muse, mutect2, varscan2
- MYL5 | chr4:673973 del AAGAGGTTGGT | 5'Flank (DEL) | VAF 82/399 reads (21%) | called by mutect2, pindel, varscan2
- NDUFS8 | c.373-534C>A | Intron (SNP) | VAF 18/269 reads (7%) | called by muse, mutect2
- NOL12 | c.-5C>A | 5'UTR (SNP) | VAF 49/347 reads (14%) | called by muse, mutect2, varscan2
- NPHS2 | c.795-9C>G | Intron (SNP) | VAF 95/672 reads (14%) | called by muse, mutect2, varscan2
- NUP35 | c.339+471C>G | Intron (SNP) | VAF 32/286 reads (11%) | called by muse, mutect2, varscan2
- OFCC1 | n.556+3414G>C | Intron (SNP) | VAF 31/115 reads (27%) | called by muse, mutect2, varscan2
- OR10V2P | n.376C>G | RNA (SNP) | VAF 95/513 reads (19%) | called by muse, mutect2, varscan2
- PCNX3 | c.3379+12C>A | Intron (SNP) | VAF 74/428 reads (17%) | called by muse, mutect2, varscan2
- PDE2A | c.704-19C>T | Intron (SNP) | VAF 118/399 reads (30%) | called by muse, mutect2, varscan2
- PIGM | c.*36C>T | 3'UTR (SNP) | VAF 37/231 reads (16%) | called by muse, mutect2, varscan2
- PLK5 | c.405+28G>C | Intron (SNP) | VAF 8/41 reads (20%) | catalogued as COSV58293117; called by muse, mutect2, varscan2
- PPARG | c.*5G>C | 3'UTR (SNP) | VAF 113/518 reads (22%) | catalogued as COSV99826184, COSV99826238; called by muse, mutect2, varscan2
- PRSS40A | n.142-2171C>A | Intron (SNP) | VAF 44/382 reads (12%) | called by muse, mutect2, varscan2
- PSMB9 | c.532+13G>T | Intron (SNP) | VAF 37/646 reads (6%) | called by muse, mutect2
- PXK | c.102+456C>T | Intron (SNP) | VAF 41/301 reads (14%) | called by muse, mutect2, varscan2
- RHOT1 | c.1333-19T>A | Intron (SNP) | VAF 26/220 reads (12%) | called by muse, mutect2, varscan2
- RNY4P30 | chr13:49890945 A>C | 5'Flank (SNP) | VAF 77/606 reads (13%) | called by muse, mutect2, varscan2
- RPL23A | c.456+51G>C | Intron (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- SCRIB | c.4696-41C>A | Intron (SNP) | VAF 66/468 reads (14%) | catalogued as rs1554632606; called by muse, mutect2, varscan2
- SDHAF2 | c.37-729C>T | Intron (SNP) | VAF 29/136 reads (21%) | called by muse, mutect2, varscan2
- SLC2A11 | c.21+1032T>A | Intron (SNP) | VAF 58/385 reads (15%) | called by muse, mutect2, varscan2
- SMAD3 | c.1010-244C>G | Intron (SNP) | VAF 140/230 reads (61%) | called by muse, mutect2, varscan2
- SMAP1 | c.118+527C>G | Intron (SNP) | VAF 55/444 reads (12%) | catalogued as rs1473249927; called by muse, mutect2, varscan2
- SRRM3 | c.-15C>G | 5'UTR (SNP) | VAF 141/531 reads (27%) | called by muse, mutect2, varscan2
- STAU2 | c.410+4053C>G | Intron (SNP) | VAF 50/252 reads (20%) | called by mutect2, varscan2
- STRN | chr2:36968494 del GAGGCC | 5'Flank (DEL) | VAF 22/154 reads (14%) | called by mutect2, pindel
- TARS1 | c.330-865C>T | Intron (SNP) | VAF 50/312 reads (16%) | called by muse, mutect2, varscan2
- TFAP2C | c.48+754G>A | Intron (SNP) | VAF 27/113 reads (24%) | called by muse, mutect2, varscan2
- TMEM184A | c.645-127C>G | Intron (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- TMEM78 | n.352C>G | RNA (SNP) | VAF 37/314 reads (12%) | called by muse, varscan2
- TNFAIP2 | c.-663-640T>A | Intron (SNP) | VAF 57/161 reads (35%) | called by muse, mutect2, varscan2
- TTBK2 | c.823-7237C>T | Intron (SNP) | VAF 174/529 reads (33%) | catalogued as rs752639148; called by muse, mutect2, varscan2
- UBA6 | chr4:67701407 C>G | 5'Flank (SNP) | VAF 95/381 reads (25%) | catalogued as rs752905892; called by muse, mutect2, varscan2
- WSCD2 | c.1346-3464G>A | Intron (SNP) | VAF 63/412 reads (15%) | catalogued as rs747728921, COSV54578418; called by muse, mutect2, varscan2
- XIAP | c.*6579A>G | 3'UTR (SNP) | VAF 15/58 reads (26%) | called by muse, mutect2, varscan2
- ZNF326 | c.-98C>G | 5'UTR (SNP) | VAF 67/345 reads (19%) | called by muse, mutect2, varscan2
- ZNF880 | chr19:52390345 G>A | 3'Flank (SNP) | VAF 29/246 reads (12%) | catalogued as rs185566949; called by muse, mutect2, varscan2
